Somatic mutation profile of tumor specimen MMRF_2310_1_BM_CD138pos (aliquot MMRF_2310_1_BM_CD138pos_T1_KHS5U_L09522) from MMRF case MMRF_2310, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.7 years (24,726 days).
Specimen MMRF_2310_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8044f74a-51fa-4d5b-8631-d41f885bf8be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2310_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2310_1_PB_CD3pos_C3_KHS5U_L09523; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80140019-dffe-4f17-aa33-91847ba780cb

The open-access MAF lists 103 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 33, Missense Mutation 30, Intron 14, Silent 12, 5'Flank 5, 3'Flank 3, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMN | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.09); catalogued as rs778644293, COSV54487026; called by muse, mutect2
- CUX2 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99918411; called by muse, mutect2, varscan2
- FAM71E2 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as rs1390984420; called by muse, mutect2
- IGHD4-11 | c.11A>T p.*4Lext*? | Nonstop Mutation (SNP) | VAF 77/77 reads (100%) | catalogued as rs782619486; called by muse, varscan2
- KCND2 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs1245637804, COSV100479148, COSV58570890; called by muse, mutect2, varscan2
- LTB | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs749816841; called by muse, mutect2, varscan2
- PKP1 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs200484616, COSV55820441; called by muse, mutect2, varscan2
- PLEKHG4B | c.3395A>G p.K1132R (on ENST00000283426; = p.K1488R on NM_052909.5) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1257179035; called by muse, mutect2, varscan2
- SATB2 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs375141410; called by muse, varscan2
- SATB2 | c.736T>A p.C246S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs372720155; called by muse, varscan2
- STAB2 | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as rs753264970, COSV101185641; called by muse, mutect2, varscan2
- TACC2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs770976617; called by muse, mutect2, varscan2
- WNT9A | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1346833153; called by muse, mutect2, varscan2
- ABCA7 | c.3986A>G p.K1329R | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3785C>T p.S1262F | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADAT1 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF4 | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CC2D1A | c.948C>T p.D316= | Splice Region (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- CIITA | c.404C>A p.P135Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CLDN22 | c.542G>C p.C181S | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERCC6L2 | c.3952G>T p.D1318Y | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- EXOC6B | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GYS1 | c.538del p.H180Mfs*19 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- H3C11 | c.217C>G p.R73G | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HSPA8 | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- IGSF9 | c.3176C>G p.A1059G (on ENST00000368094 / NM_001135050.2; = p.A1043G on NM_020789.4) | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- NCOA2 | c.922C>G p.H308D | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- NPHP1 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NR3C1 | c.31A>G p.R11G | Missense Mutation (SNP) | VAF 116/258 reads (45%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, varscan2
- PLEKHJ1 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TENT5C | c.193_216del p.K65_N72del | In Frame Del (DEL) | VAF 40/96 reads (42%) | called by mutect2, pindel, varscan2
- TENT5C | c.413_414del p.Y138Cfs*12 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- TNFRSF8 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF180 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF703 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 104/193 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ADD2 | c.885G>A p.L295= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs781807374; called by muse, mutect2, varscan2
- CHST11 | c.483G>A p.L161= | Silent (SNP) | VAF 18/338 reads (5%) | catalogued as COSV100359309; called by muse, mutect2
- CIITA | c.405A>G p.P135= | Silent (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1620C>T p.I540= | Silent (SNP) | VAF 71/156 reads (46%) | called by muse, mutect2, varscan2
- DGKD | c.3111C>T p.F1037= (on ENST00000264057 / NM_152879.3; = p.F993= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as rs190346249, COSV51033016, COSV51053940; called by muse, mutect2, varscan2
- ENDOD1 | c.1389C>T p.V463= | Silent (SNP) | VAF 107/212 reads (50%) | catalogued as rs1413873619, COSV99566281; called by muse, mutect2, varscan2
- FHAD1 | c.4131C>A p.T1377= | Silent (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- HOXA9 | c.813C>T p.D271= | Silent (SNP) | VAF 112/248 reads (45%) | catalogued as rs767844804, COSV58656556; called by muse, mutect2
- IL31RA | c.1668T>G p.T556= | Silent (SNP) | VAF 78/156 reads (50%) | called by muse, mutect2, varscan2
- ITGAE | c.1800C>T p.P600= | Silent (SNP) | VAF 81/81 reads (100%) | catalogued as rs1209891419; called by muse, mutect2, varscan2
- PKP1 | c.471C>T p.P157= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs781565843; called by muse, mutect2, varscan2
- USH2A | c.9807C>T p.G3269= | Silent (SNP) | VAF 60/106 reads (57%) | called by muse, mutect2, varscan2
- ANKRD17 | c.*128G>A | 3'UTR (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- ANKRD31 | c.*21T>G | 3'UTR (SNP) | VAF 120/238 reads (50%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020947 C>A | 5'Flank (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021395 G>T | 5'Flank (SNP) | VAF 77/142 reads (54%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021491 A>G | 5'Flank (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- C8orf37 | c.*2545T>G | 3'UTR (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- CALCRL | c.*438A>C | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- CAPZA2 | chr7:116862572 del GCT | 5'Flank (DEL) | VAF 4/42 reads (10%) | catalogued as rs754710280; called by mutect2, pindel
- CCDC153 | c.257-79C>T | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2
- CFAP44 | c.*413A>T | 3'UTR (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- CXCL14 | c.*9A>C | 3'UTR (SNP) | VAF 136/275 reads (49%) | catalogued as COSV100463718; called by muse, mutect2, varscan2
- ERC1 | c.*4332_*4335del | 3'UTR (DEL) | VAF 71/80 reads (89%) | catalogued as rs1452648782; called by mutect2, varscan2
- EVC | c.*3162T>A | 3'UTR (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- EYS | c.1766+4145T>G | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- EYS | c.1766+3100T>A | Intron (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- FAM8A1 | c.*162G>A | 3'UTR (SNP) | VAF 69/167 reads (41%) | called by muse, mutect2, varscan2
- GAB1 | c.*215A>G | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- GPR62 | c.-17G>A | 5'UTR (SNP) | VAF 82/142 reads (58%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.*2449C>T | 3'UTR (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- HHEX | c.*385T>C | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- LACTB2 | c.123-1204C>T | Intron (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- MAP3K13 | c.*6403G>A | 3'UTR (SNP) | VAF 42/92 reads (46%) | catalogued as COSV53993133; called by muse, mutect2, varscan2
- MCM8 | chr20:5995227 del ATTT | 3'Flank (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- MECR | c.*223C>T | 3'UTR (SNP) | VAF 38/81 reads (47%) | catalogued as rs528665448; called by muse, mutect2, varscan2
- MMP16 | c.*380dup | 3'UTR (INS) | VAF 46/114 reads (40%) | called by mutect2, pindel, varscan2
- MSC | c.*533C>T | 3'UTR (SNP) | VAF 77/184 reads (42%) | called by muse, mutect2, varscan2
- MSH6 | chr2:47806969 C>T | 3'Flank (SNP) | VAF 70/169 reads (41%) | catalogued as rs768061728; called by muse, mutect2, varscan2
- NAALADL2 | c.*1122C>A | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- NKD1 | c.193-1652C>G | Intron (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2, varscan2
- NOVA1 | c.*493T>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- NTM | c.934+42T>G | Intron (SNP) | VAF 75/148 reads (51%) | catalogued as rs776189864; called by muse, mutect2, varscan2
- NTN1 | c.*1834C>T | 3'UTR (SNP) | VAF 73/77 reads (95%) | called by muse, mutect2, varscan2
- OSBPL11 | c.*1119A>G | 3'UTR (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- PANK3 | c.*722_*729del | 3'UTR (DEL) | VAF 44/114 reads (39%) | called by mutect2, varscan2
- PCSK7 | c.*493G>C | 3'UTR (SNP) | VAF 82/183 reads (45%) | called by muse, mutect2, varscan2
- RAF1 | c.1109-66A>G | Intron (SNP) | VAF 32/75 reads (43%) | called by muse, varscan2
- REG3A | c.-34-24T>C | Intron (SNP) | VAF 76/140 reads (54%) | called by muse, mutect2, varscan2
- RGS4 | chr1:163068996 A>C | 5'Flank (SNP) | VAF 70/163 reads (43%) | called by muse, mutect2, varscan2
- RNF217 | c.*1479del | 3'UTR (DEL) | VAF 30/75 reads (40%) | catalogued as rs1245948838; called by mutect2, varscan2
- SCN3B | c.*22+101A>C | Intron (SNP) | VAF 140/279 reads (50%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.*18C>G | 3'UTR (SNP) | VAF 4/91 reads (4%) | called by muse, mutect2
- SLC22A9 | c.*428_*432dup | 3'UTR (INS) | VAF 21/90 reads (23%) | catalogued as rs1239804485; called by mutect2, varscan2*
- SLC5A8 | c.*704T>G | 3'UTR (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- TCHP | c.1320+26G>A | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as rs1247941532; called by muse, mutect2
- TECRL | c.730+14C>A | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- TEX261 | c.*1664G>A | 3'UTR (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- TMBIM6 | c.-31+550G>A | Intron (SNP) | VAF 41/82 reads (50%) | catalogued as rs1049749495, COSV57278519, COSV99920664; called by muse, mutect2, varscan2
- TMEM47 | c.*856_*860del | 3'UTR (DEL) | VAF 30/34 reads (88%) | called by pindel, varscan2
- TMEM47 | c.*850T>C | 3'UTR (SNP) | VAF 28/30 reads (93%) | called by muse, varscan2
- TROAP | c.-5-80G>A | Intron (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- TSPYL2 | c.*176G>A | 3'UTR (SNP) | VAF 22/22 reads (100%) | catalogued as rs1194367305; called by muse, mutect2, varscan2
- USP14 | c.*51A>T | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2
- USP31 | c.*4457_*4461del | 3'UTR (DEL) | VAF 89/152 reads (59%) | catalogued as rs1388800903; called by mutect2, pindel, varscan2
- USP34 | c.6843-40T>C | Intron (SNP) | VAF 38/65 reads (58%) | called by muse, mutect2, varscan2
- ZNF618 | chr9:114050366 G>A | 3'Flank (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2
- ZNF687 | c.*662C>A | 3'UTR (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
